Surgical pathology report (de-identified scan), TCGA case TCGA-T7-A92I, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Molecular Response, specimen TCGA-T7-A92I-01A (Primary Tumor).

[page 1 of 5]
1000.3
Carcinoma, clear cell 8310/3
Carcinoma, renal cell 8312/3
Site: @ Kidney NOS. 0649
4/13/14

4E/37C

Tissue/Blood Requisition Form

Subject Number:

Retain original and email/fax copy to

Retain original and email/fax copy to _____	
Sample Collection Date:	Procured by: _____
Time of Tumor Sample Excision (24 hour clock):	Time Zone: _____

TUMOR-FROZEN & FRESH SAMPLES

TUMOR-FROZEN & FRESH SAMPLES
FROZEN SAMPLES BATCH SHIPPED (dry ice); FRESH TUMOR SAMPLE, IF COLLECTED, SHIPPED ON DAY OF COLLECTION

Collect resected tumor in accordance with standard procedures. Weigh the sample and section off ~100mg.

Frozen Tumor (Required)

Frozen Tumor (Required)
Place this sample in the cryovial labeled Frozen Tumor sample and record the weight. Place the cryovial in a can and then into the vapor phase dewar. Record the time placed in dewar.

Weight of Tissue: 60 mg
(tissue weight must be ≥ 100 mg)

Time placed in dewar: _____
(24 hour clock) H H : M M

Fresh Tumor (Optional) ☐ N/A

Fresh Tumor (Optional) ☐ N/A
Locate the "Fresh Tumor" label in the kit and affix to the 15ml tube (sent separately). Place any remaining tumor tissue into the 15ml conical tube containing

Weight of Tissue: 70 mg Time placed in _____ Lot Number of _____
(no min. weight specified) (24 hour clock) H H : M M

WHOLE BLOOD SAMPLE (Required) - BATCHED SHIPPED FROZEN (dry ice)

Sample Collection Date:	D D . M M / Y Y Y Y	Procured by: _____
Time of Blood Sample Collection (24 hour clock):	H H : M M	Time Zone: _____

1-10ml EDTA tube. Fill tube completely and mix by gentle inversion at least 8-10 times. Freeze sample on dry ice or place in vapor phase dewar.

Time placed in dry ice/dewar: _____
(24 hour clock) H H : M M

BASIC PATHOLOGICAL INFORMATION

Clinical Diagnosis:
(Ex. Lung Cancer)

Renal Cancer

Source of Specimen:
(Ex. Right Lung)

Right Kidney

[page 2 of 5]
Tissue/Blood Requisition Form

Site ID:

Subject Number:

Diagnostic Slides (Required) - SLIDES BATCHED SHIPPED (ambient)			
From the diagnostic FFPE block, cut 3 slides with one section ~ 4-5µm on each slide. Label the frosted tip of the slide in pencil with the sample ID (located on the label at the top of this form). Record the ID number of the diagnostic histology cassette and the number of slides. H&E stain the slides and store in a slide mailer.			
Diagnostic Histology Cassette ID		Number of Slides Cut 3	
Refer to Study Manual for detailed specimen processing and shipping instructions: (* denotes required samples)			
Specimen	Collection Vessel	Transfer Tube	Shipping Status
Frozen Tumor*	None	Cryovial	Same Day – Dry Ice
Frozen Blood*	1-10ml EDTA	None	Same Day – Dry Ice
Fresh Tumor	None	15ml-	Same Day – Refrigerated
Diagnostic Slides*	Histology Cassette	SuperFrost Slides	5-Slide Mailer—Batch
When FROZEN and FRESH samples are ready for shipment please notify by Email notification: At this time, please also provide your Sample Manifest.			
When the Diagnostic slides are ready for shipment please notify by Email notification: At this time, please also provide your Sample Manifest.			
DO NOT RETURN EMPTY CONTAINERS TO:			
White copy-Retain for your Records		Yellow copy-send to pathology for diagnostic slides	

[page 3 of 5]
Surg Path Final Report

* Final Report *

Result Type: Surg Path Final Report
Result Date:
Result Status: Auth (Verified)
Result Title: Surgical Pathology Final Report
Verified By:
Encounter info:

* Final Report *

Final Diagnosis (Verified)

Right partial nephrectomy with ORC:

Renal cell carcinoma, usual type.

Tumor measures 3 x 1.5 cm.

Tumor extends to inked capsule but does not penetrate the capsule.

Tissue labeled "fat overlying kidney" shows no evidence of involvement.

Kidney parenchymal surgical margin is free and measures approximately 1.5 mm.

No lymphovascular or perineural involvement is noted.

Fuhrmann nuclear grade: majority of the tumor is grade II.

Focal areas reveal Fuhrmann nuclear grade of III.

Tumor is positive for immunoperoxidase stain for RCC and predominantly negative for immunoperoxidase stain for E-cadherin.

AJCC: T1a,NX

Fat overlying kidney:

No evidence of tumor involvement.

GENERAL COMMENT REGARDING IMMUNOPEROXIDASE AND IN SITU HYBRIDIZATION STUDIES: "Performance characteristics for some analytes have been determined by [redacted] They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These [redacted] are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing."

Signature Line

[Redacted Signature]

Printed by:
Printed on:

[Redacted]

Page 1 of 2
(Continued)

[page 4 of 5]
Surg Path Final Report

* Final Report *

Performing Lab (Verified)

Final diagnosis rendered at

Gross Description (Verified)

"A, Right kidney mass." Received is a 4 x 2.2 cm portion of kidney with a small amount of attached fat. The specimen has previously been inked by the pathologist as follows: surgical margin = black, surface capsule = orange. The specimen has previously been sectioned by the pathologist, and there is a 3 x 1.5 cm soft, yellow-tan mass, which abuts the renal capsule and comes to within 0.2 cm of the surgical margin. The remaining renal parenchyma is tan, and no additional lesions or areas of interest are grossly identified. "A1-A3," representative.

"B, Fat overlying kidney." Received is a 6.2 x 3.5 cm portion of yellow, lobulated tissue. On sectioning, the cut surface is yellow and fatty, and no lesions or additional areas of interest are grossly identified. inked black. "B," 2p, representative.

Signature Line

Operating Room Consultation (Verified)

Time In: Time Out:

A. Right partial kidney.

B. Fat overlying tumor of right kidney.

A. Right partial nephrectomy

4 x 2.2 cm segment of kidney with 3 x 1.5 cm mass extending above surface with intact capsule and small amount of fat. Margin inked black. Surface capsule inked orange. Sections show rounded yellow mass sampled for Remainder for permanents.

B. Also received is a segment of fat "fat overlying kidney" submitted in formalin specimen.

Clinical Information (Verified)

Right renal tumor.

Completed Action List:

* Order by

* Order by

* VERIFY by

Printed by:
Printed on:

Page 2 of 2
(End of Report)

*Per TSS dx discrepancy form,
TCGA tumor is carcinoma,
char cell renal.*

[page 5 of 5]
TCGA Pathologic Diagnosis Discrepancy Form

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information			
#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Renal Carcinoma	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Kidney Renal Clear Cell Carcinoma	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form			
3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	The diagnosing pathologist reviewed the case and found that it was a variant of clear cell called granular clear cell and that he did not put that information on the path report as an oversight	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file bc0ef3a7-845b-4d1d-b07f-2687b37f36ac (TCGA-T7-A92I.CF9C938A-E693-4DCF-864E-F39F974E757C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).